Gene-level copy-number profile of tumor specimen TCGA-CV-7247-01A from TCGA case TCGA-CV-7247, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 55.9 years (20,433 days).
Specimen TCGA-CV-7247-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.5b82a03a-58ec-4009-8213-77e8e78ca705.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7247-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6fc9ead2-c16a-4679-b2ae-f564ad4c7035

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 1,087; copy number 2: 17,045; copy number 3: 31,154; copy number 4: 8,402; copy number 5: 655; copy number 6: 782; copy number 8: 8; copy number 9: 50; copy number 11: 92; copy number 14: 4; copy number 16: 233; copy number 17: 67; copy number 19: 86; copy number 23: 46; copy number 37: 100.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7247-01A-11D-2010-01): tumor purity 0.46, ploidy 4.96, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:1,507,322–2,245,605, 6 genes (within-gene range 0–3): RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 686 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:89,107,621–90,261,708, 8 genes, copy number 8 (within-gene range 2–8): EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr7:89,443,946–113,494,870, 496 genes, copy number 9–37 (broad region; genes not listed).
- chr11:66,848,417–66,958,386, 1 gene, copy number 14 (within-gene range 2–14): PC.
- chr11:66,919,762–71,928,654, 181 genes, copy number 11–19 (within-gene range 2–19) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,087. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
